Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042794-09A.3 (aliquot TARGET-15-SJMPAL042794-09A.3-01D) from TARGET case TARGET-15-SJMPAL042794, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.2 years (5,541 days).
Specimen TARGET-15-SJMPAL042794-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edf81d9e-09e6-44ae-bd41-498b4c75395c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042794-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042794-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eeaadbd-1628-4a87-939a-2dfcc9f4c6ed

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERC1 | c.2899C>A p.R967S (on ENST00000360905 / NM_178040.4; = p.R939S on NM_178039.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs947043181; called by muse, mutect2
- GATA2 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559986079; called by muse, mutect2, varscan2
- CEP85L | c.2269G>T p.A757S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by mutect2, varscan2
- RHPN2 | c.1498-41C>T | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as rs878870194; called by muse, varscan2
